Gene-level copy-number profile of tumor specimen AP-EPNF-XC from APOLLO case AP-EPNF, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Lepidic adenocarcinoma; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2.
Specimen AP-EPNF-XC: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ffbb2700-2d95-4f16-9859-a46e6bb75880.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-EPNF-LS (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,233 have no estimate.
https://portal.gdc.cancer.gov/files/864ce763-22a9-4b27-a404-af3b01b7296a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 46; copy number 1: 12,994; copy number 2: 38,462; copy number 3: 5,635; copy number 4: 904; copy number 5: 245; copy number 6: 87; copy number 8: 10; copy number 10: 7.

Homozygous deletions (total copy number 0; autosomes only): 46 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,326,201–2,326,693, 1 gene (within-gene range 0–2): AL589739.1.
- chr1:246,690,047–246,691,821, 1 gene: AL591848.1.
- chr2:89,297,264–89,600,680, 5 genes: IGKV1-37, IGKV2-38, IGKV1-39, IGKV2-40, 5S_rRNA.
- chr5:174,751,734–174,751,787, 1 gene (within-gene range 0–2): MIR4634.
- chr10:38,601,418–38,605,609, 1 gene: ABCD1P2.
- chr10:38,783,004–38,783,108, 1 gene: AL590623.1.
- chr13:100,027,769–100,028,174, 1 gene: NDUFA12P1.
- chr13:100,062,296–100,063,601, 1 gene: ASNSP3.
- chr16:28,341,437–28,455,356, 8 genes: AC138904.2, NPIPB6, AC138894.3, EIF3CL, MIR6862-1, CDC37P2, AC138894.4, AC138894.2.
- chr16:28,456,372–28,471,175, 1 gene (within-gene range 0–2): NPIPB7.
- chr19:54,379,489–54,438,346, 5 genes: AC245884.4, TTYH1, AC245884.1, AC245884.9, AC245884.10.
- chr21:9,026,821–9,914,846, 17 genes: CDRT15P9, CR392039.4, TEKT4P2, SOWAHCP2, CR392039.2, CR381653.1, SNX18P12, CR381653.2, NCOR1P4, AC124864.1, AC124864.2, U1, LINC01667, AC018692.2, RN7SL52P, SNORA70, AC018692.1.
- chr21:10,640,028–13,016,692, 3 genes: AF254982.1, IGHV1OR21-1, AP001464.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 349 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:186,567,403–186,585,800, 1 gene, copy number 5 (within-gene range 2–5): DNAJB11.
- chr12:26,905,181–27,014,434, 4 genes, copy number 5: INTS13, FGFR1OP2, TM7SF3, AC024896.1.
- chr12:28,821,975–29,784,759, 15 genes, copy number 5–6: AC022081.1, AC024255.1, AC012150.1, FAR2, AC012150.2, AC009318.4, AC009318.1, AC009318.3, AC009318.2, ERGIC2, OVCH1-AS1, OVCH1, TMTC1, AC009320.1, RPL21P99.
- chr12:38,994,803–40,106,089, 12 genes, copy number 5–6 (within-gene range 3–6): AC018448.2, AC018448.1, LINC02406, AC084373.1, KIF21A, AC121334.1, AC121334.2, ABCD2, AC121334.3, C12orf40, SLC2A13, AC121336.1.
- chr12:55,743,122–56,787,790, 74 genes, copy number 6 (broad region; genes not listed).
- chr12:61,231,159–71,441,898, 207 genes, copy number 5–10 (within-gene range 2–10) (broad region; genes not listed).
- chr16:30,267,553–30,523,567, 22 genes, copy number 5: SMG1P5, AC106782.4, CD2BP2, CD2BP2-DT, TBC1D10B, AC106782.5, MYLPF, ZNF48, SEPTIN1, AC116348.4, ZNF771, SNORA80C, DCTPP1, SEPHS2, Y_RNA, Y_RNA, ITGAL, AC116348.3, AC116348.1, RNU7-61P, AC116348.2, MIR4518.
- chr16:31,060,843–31,150,083, 14 genes, copy number 5 (within-gene range 4–5): ZNF668, AC135050.4, ZNF646, PRSS53, AC135050.2, VKORC1, AC135050.7, BCKDK, KAT8, AC135050.5, AC135050.6, AC009088.3, PRSS8, PRSS36.

Autosomal genes at a single copy (total copy number 1): 12,994. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
